Gene-level copy-number profile of tumor specimen C3N-00953-02 from CPTAC case C3N-00953, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 41.4 years (15,137 days).
Specimen C3N-00953-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1b7b609d-ce70-4881-aadf-6481e7ade52f.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00953-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,708 have no estimate.
https://portal.gdc.cancer.gov/files/558964ba-bc70-4726-9e7c-90cd0ed5db48

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,477; copy number 1: 7,131; copy number 2: 45,675; copy number 3: 727; copy number 4: 2,901; copy number 5: 3; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): 2,468 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:199,760,544–201,927,543, 74 genes (broad region; genes not listed).
- chr2:203,190,780–242,175,634, 742 genes (within-gene range 0–2) (broad region; genes not listed).
- chr6:1,312,098–1,324,022, 2 genes: FOXQ1, LINC01394.
- chr14:21,941,128–22,552,156, 109 genes (within-gene range 0–1) (broad region; genes not listed).
- chr14:35,538,352–35,932,325, 8 genes (within-gene range 0–1): RALGAPA1, AL137818.1, QRSL1P3, AL162311.3, NUTF2P2, BRMS1L, AL162311.1, AL162311.2.
- chr14:43,990,539–106,879,812, 1,533 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,412,264, 3 genes, copy number 5–11: CR383658.1, RNU6-458P, CR383658.2.

Autosomal genes at a single copy (total copy number 1): 4,297. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
